Somatic mutation profile of tumor specimen TCGA-S9-A89V-01A (aliquot TCGA-S9-A89V-01A-11D-A36O-08) from TCGA case TCGA-S9-A89V, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.0 years (25,570 days).
Specimen TCGA-S9-A89V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c620f973-da7f-4c19-8f4b-f7553a46be72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A89V-10A (Blood Derived Normal), aliquot TCGA-S9-A89V-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/136f7592-94b4-4cb0-a3a4-72bbc6ec38e8

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Frame Shift Del 3, Splice Site 3, Intron 2, Frame Shift Ins 2, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC2 | c.2357G>A p.W786* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | catalogued as rs201757827, COSV100933592; called by muse, mutect2
- ATP6V1G3 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV55278495; called by muse, mutect2, varscan2
- AXDND1 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100858479; called by muse, mutect2, varscan2
- DHX35 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99326990; called by muse, mutect2, varscan2
- DNMT3A | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767224028, COSV53054134, COSV53060524; called by muse, mutect2, varscan2
- GRIK1 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100517158; called by muse, mutect2, varscan2
- HMCN1 | c.13454G>A p.R4485Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374051668, COSV54876527; called by muse, mutect2, varscan2
- HMMR | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as COSV100701015; called by muse, mutect2, varscan2
- ITIH6 | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV99513470; called by muse, mutect2
- JMJD4 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100248272; called by muse, mutect2, varscan2
- KIR2DL4 | c.134C>T p.T45M (on ENST00000396284; = p.T6M on NM_001080770.2) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs779579931; called by muse, mutect2, varscan2
- LRP2 | c.4682C>T p.P1561L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780636146, COSV99789067; called by muse, mutect2, varscan2
- MCOLN1 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99900676; called by muse, mutect2
- MYH1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432611647, COSV56848015; called by muse, mutect2, varscan2
- NF1 | c.6705-2A>T p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 32/101 reads (32%) | catalogued as CS1413893, COSV100647415; called by muse, mutect2, varscan2
- OR10G8 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV101461848; called by muse, mutect2, varscan2
- OR1M1 | c.215G>C p.C72S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs756587416, COSV101447570; called by muse, mutect2, varscan2
- PKD2L2 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99296433; called by muse, mutect2
- PKP4 | c.246-1G>A p.X82_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as COSV101081113; called by muse, mutect2
- PLA2R1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99323057; called by muse, mutect2, varscan2
- RAB19 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV99325143; called by muse, varscan2
- RBMY1E | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.031); catalogued as COSV100740353; called by muse, mutect2, varscan2
- RNF125 | c.602A>C p.D201A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV99470543; called by muse, mutect2
- SLC15A1 | c.1936-2A>G p.X646_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100919502; called by muse, mutect2, varscan2
- SLC18A2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1294465425, COSV100041770; called by muse, mutect2, varscan2
- SOHLH2 | c.824G>C p.C275S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101157953; called by muse, mutect2, varscan2
- ULBP3 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as rs1484606727, COSV100949635; called by muse, mutect2, varscan2
- UMODL1 | c.3499G>A p.D1167N (on ENST00000408910 / NM_001004416.2; = p.D1295N on NM_173568.3) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV68569887; called by muse, mutect2, varscan2
- ARID2 | c.3332dup p.Q1112Afs*48 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- ATRX | c.3920del p.N1307Mfs*39 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | called by mutect2, pindel, varscan2
- NF1 | c.978dup p.L327Tfs*3 | Frame Shift Ins (INS) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.1008del p.F336Lfs*87 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- TSPAN3 | c.676_684del p.G226_L228del | In Frame Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- TTBK2 | c.2306_2310del p.E769Gfs*8 | Frame Shift Del (DEL) | VAF 25/204 reads (12%) | called by mutect2, pindel, varscan2
- CNGA2 | c.1542G>A p.S514= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs185584985, COSV100323779; called by muse, mutect2, varscan2
- CTC1 | c.1866A>G p.Q622= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV100236033, COSV100236533; called by muse, mutect2, varscan2
- CXCR2 | c.111C>T p.A37= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV100578989; called by muse, mutect2, varscan2
- FAM222B | c.1428C>T p.H476= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1435208668, COSV100368614; called by muse, mutect2, varscan2
- FLT4 | c.3654G>A p.P1218= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs745672269, COSV99987503; called by muse, mutect2, varscan2
- KCNQ3 | c.2106G>A p.V702= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs774327034, COSV101196209; called by muse, mutect2, varscan2
- KRT25 | c.1179C>A p.A393= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV100379974, COSV56445699; called by muse, mutect2
- MAP3K19 | c.2205G>A p.E735= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100208746; called by muse, mutect2, varscan2
- MGA | c.3621A>G p.K1207= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV54949978; called by muse, mutect2, varscan2
- POM121C | c.2907C>A p.G969= (on ENST00000607367; = p.G727= on NM_001099415.3) | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- RAI1 | c.843G>A p.Q281= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs748280748, COSV55388680, COSV55398332; called by muse, varscan2
- UPF1 | c.2115G>A p.R705= (on ENST00000599848 / NM_001297549.2; = p.R694= on NM_002911.4) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99439802; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149820 G>A | 5'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- AKAP7 | c.851-28442T>C | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99541609; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1399C>T | Intron (SNP) | VAF 10/67 reads (15%) | catalogued as rs746779551, COSV63750597; called by muse, mutect2, varscan2
